Somatic mutation profile of tumor specimen ALCH-B4B8-TTP1-A (aliquot ALCH-B4B8-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B4B8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.3 years (25,663 days).
Specimen ALCH-B4B8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba3f463e-b1f3-45f7-94e7-660aefcc4d92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4B8-NB1-A (Blood Derived Normal), aliquot ALCH-B4B8-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcfbf9ea-a2bf-43c7-9bbe-6c4f8fedb965

The open-access MAF lists 153 somatic variants for this specimen: 101 protein-altering or splice-affecting, 34 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 34, Intron 9, Nonsense Mutation 5, RNA 4, Translation Start Site 2, 5'UTR 2, Frame Shift Del 2, Splice Site 2, 3'UTR 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 191/813 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AHNAK2 | c.11857G>A p.D3953N | Missense Mutation (SNP) | VAF 42/848 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs775373086; called by muse, mutect2
- ARMCX5-GPRASP2 | c.634A>G p.K212E | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs1270427176; called by muse, mutect2, varscan2
- AUH | c.1004G>T p.R335L | Missense Mutation (SNP) | VAF 108/591 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV57861958; called by muse, mutect2, varscan2
- C1S | c.1597G>C p.V533L | Missense Mutation (SNP) | VAF 32/796 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as COSV61070682; called by muse, mutect2
- CACNA1A | c.4486G>A p.V1496I | Missense Mutation (SNP) | VAF 56/742 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.66); catalogued as rs121908234, CM041264; ClinVar: not provided; called by muse, mutect2
- CASP2 | c.1218G>T p.M406I | Missense Mutation (SNP) | VAF 150/1606 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.145); catalogued as COSV60082266; called by muse, mutect2
- CFHR5 | c.922A>G p.M308V | Missense Mutation (SNP) | VAF 22/690 reads (3%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1558287665; called by muse, mutect2
- CNTNAP2 | c.1174C>G p.Q392E | Missense Mutation (SNP) | VAF 124/831 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62243961; called by muse, mutect2, varscan2
- CNTRL | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 106/532 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs200516440, COSV53048818; called by muse, mutect2, varscan2
- COL1A2 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 112/1862 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.287); catalogued as rs755610740; ClinVar: uncertain significance; called by muse, mutect2
- COMP | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 22/490 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99721347; called by muse, mutect2
- CORO2A | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 82/705 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as COSV59661944; called by muse, mutect2, varscan2
- CSMD3 | c.5956A>G p.T1986A (on ENST00000297405 / NM_001363185.1; = p.T1882A on NM_052900.3) | Missense Mutation (SNP) | VAF 34/1350 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV99851158; called by muse, mutect2
- CST9 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 122/704 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as rs527608819; called by muse, mutect2, varscan2
- DNAJB4 | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66131996; called by muse, mutect2, varscan2
- EEF1A2 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 44/464 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV99035645; called by muse, mutect2
- ENAM | c.2533C>T p.H845Y | Missense Mutation (SNP) | VAF 34/1366 reads (2%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs1003299279; called by muse, mutect2
- GANAB | c.2023G>A p.A675T | Missense Mutation (SNP) | VAF 60/970 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as COSV60466873; called by muse, mutect2
- GRM8 | c.1845G>T p.R615S | Missense Mutation (SNP) | VAF 45/764 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV58867386; called by muse, mutect2
- KCNC1 | c.406del p.A136Pfs*16 | Frame Shift Del (DEL) | VAF 30/297 reads (10%) | catalogued as COSV56393492; called by mutect2, pindel, varscan2
- KCND3 | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 48/897 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.37); catalogued as rs760710842, COSV56180280, COSV56191155; called by muse, mutect2
- KRT33A | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 46/458 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as rs777073996; called by muse, mutect2, varscan2
- LHFPL2 | c.66del p.F22Lfs*8 | Frame Shift Del (DEL) | VAF 16/150 reads (11%) | catalogued as rs1201463338; called by mutect2, varscan2
- LPIN1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 44/394 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.888); catalogued as rs1172290138; called by muse, mutect2, varscan2
- MAEA | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 46/560 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.021); catalogued as rs938059546; called by muse, mutect2
- MAGI2 | c.1546C>G p.P516A | Missense Mutation (SNP) | VAF 48/1284 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV104415196; called by muse, mutect2
- MDM1 | c.1808A>G p.D603G | Missense Mutation (SNP) | VAF 36/732 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1205956560; called by muse, mutect2
- MRPL37 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 19/269 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1191164267; called by muse, mutect2
- MTBP | c.2671G>A p.V891I | Missense Mutation (SNP) | VAF 74/381 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as rs746420458; called by muse, mutect2, varscan2
- NFKB2 | c.2390G>A p.R797H | Missense Mutation (SNP) | VAF 77/444 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs114461415; called by muse, mutect2, varscan2
- OR10H3 | c.376A>G p.T126A | Missense Mutation (SNP) | VAF 17/474 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59944346; called by muse, mutect2
- OR4C15 | c.474C>A p.H158Q (on ENST00000314644; = p.H104Q on NM_001001920.2) | Missense Mutation (SNP) | VAF 159/808 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs765828781; called by muse, mutect2, varscan2
- PKHD1 | c.3244A>G p.I1082V | Missense Mutation (SNP) | VAF 38/836 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV61890276; called by muse, mutect2
- PLCXD3 | c.381G>C p.E127D | Missense Mutation (SNP) | VAF 144/755 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.132); catalogued as COSV100125860; called by muse, mutect2, varscan2
- PTCHD3 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs906486079; called by muse, mutect2, varscan2
- RBMXL3 | c.2815C>T p.R939W | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.531); catalogued as rs1010569231, COSV57750001; called by muse, mutect2, varscan2
- RYR2 | c.1273C>T p.L425F | Missense Mutation (SNP) | VAF 69/908 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs1384379806; called by muse, mutect2
- SERPINB10 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 82/1100 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs142349456; called by muse, mutect2
- SI | c.2461G>C p.G821R | Missense Mutation (SNP) | VAF 28/573 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV52284717; called by muse, mutect2
- SLC4A2 | c.2824A>G p.I942V | Missense Mutation (SNP) | VAF 54/550 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52542449; called by muse, mutect2
- SYNE2 | c.9609G>A p.M3203I | Missense Mutation (SNP) | VAF 50/571 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs767185752; called by muse, mutect2
- TMEM130 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 20/592 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs369651719; called by muse, mutect2
- UGT1A7 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 64/746 reads (9%) | catalogued as rs753533001; called by muse, mutect2
- UQCR11 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 17/314 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.243); catalogued as rs1185434569; called by muse, mutect2
- WDR70 | c.329C>G p.S110C | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as COSV54265558; called by muse, mutect2
- ZFHX3 | c.10847C>G p.S3616C | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.346); catalogued as COSV51706837; called by muse, mutect2
- ANKRD36C | c.2852G>T p.R951M | Missense Mutation (SNP) | VAF 103/1280 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.859); called by muse, mutect2
- ASPHD2 | c.236G>C p.G79A | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- CCDC168 | c.20698G>A p.E6900K | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.047); called by muse, mutect2
- CFAP46 | c.5907A>T p.Q1969H | Missense Mutation (SNP) | VAF 74/849 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- COL1A2 | c.1049C>A p.P350Q | Missense Mutation (SNP) | VAF 106/1840 reads (6%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.832); called by muse, mutect2
- COL6A2 | c.120G>T p.K40N | Missense Mutation (SNP) | VAF 141/947 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DOCK7 | c.643C>G p.P215A | Missense Mutation (SNP) | VAF 40/740 reads (5%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by muse, mutect2
- EXOC2 | c.2457A>T p.E819D | Missense Mutation (SNP) | VAF 22/552 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- F13B | c.1305A>C p.K435N | Missense Mutation (SNP) | VAF 30/691 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2
- FGF23 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 29/723 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.535); called by muse, mutect2
- GLRB | c.472C>A p.Q158K | Missense Mutation (SNP) | VAF 81/322 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- GLT1D1 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 24/693 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2
- HHAT | c.1174A>T p.N392Y | Missense Mutation (SNP) | VAF 34/1042 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IPO4 | c.3178C>T p.Q1060* | Nonsense Mutation (SNP) | VAF 22/402 reads (5%) | called by muse, mutect2
- ITPKC | c.1387G>T p.D463Y | Missense Mutation (SNP) | VAF 143/1530 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- JSRP1 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by mutect2, varscan2
- LDB3 | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 21/552 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2
- LECT2 | c.426T>A p.C142* | Nonsense Mutation (SNP) | VAF 53/454 reads (12%) | called by muse, mutect2, varscan2
- LRP2 | c.3707A>T p.Q1236L | Missense Mutation (SNP) | VAF 65/640 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- LTB4R | c.347C>A p.S116* | Nonsense Mutation (SNP) | VAF 59/397 reads (15%) | called by muse, mutect2, varscan2
- MAP3K4 | c.2255+1G>C p.X752_splice | Splice Site (SNP) | VAF 10/194 reads (5%) | called by muse, mutect2
- MBD1 | c.965A>G p.D322G | Missense Mutation (SNP) | VAF 32/903 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2
- MDM1 | c.1809C>G p.D603E | Missense Mutation (SNP) | VAF 36/736 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2
- MEI1 | c.1807A>T p.I603L | Missense Mutation (SNP) | VAF 42/520 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.198); called by muse, mutect2
- MUC16 | c.26843C>A p.A8948D | Missense Mutation (SNP) | VAF 36/605 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); called by muse, mutect2
- NKAP | c.1007A>T p.E336V | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NPC1L1 | c.3104C>G p.S1035C | Missense Mutation (SNP) | VAF 38/1194 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- OR2W3 | c.250A>G p.N84D | Missense Mutation (SNP) | VAF 50/688 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHGB2 | c.1127C>A p.S376Y | Missense Mutation (SNP) | VAF 44/758 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- PKD2L1 | c.350-2A>G p.X117_splice | Splice Site (SNP) | VAF 18/166 reads (11%) | called by muse, mutect2, varscan2
- PLD1 | c.2476G>T p.G826W | Missense Mutation (SNP) | VAF 28/644 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POF1B | c.78G>T p.Q26H | Missense Mutation (SNP) | VAF 108/572 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- POP1 | c.2620A>G p.M874V | Missense Mutation (SNP) | VAF 308/1841 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- PPP1R11 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 15/212 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2
- RAI1 | c.5602G>T p.G1868W | Missense Mutation (SNP) | VAF 54/698 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- REM2 | c.871C>A p.P291T | Missense Mutation (SNP) | VAF 18/271 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- RNF222 | c.626T>A p.I209N | Missense Mutation (SNP) | VAF 66/758 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, mutect2
- ROS1 | c.6594G>A p.W2198* | Nonsense Mutation (SNP) | VAF 20/236 reads (8%) | called by muse, mutect2
- RYR2 | c.7932G>T p.L2644F | Missense Mutation (SNP) | VAF 38/461 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- RYR2 | c.8863C>A p.P2955T | Missense Mutation (SNP) | VAF 24/579 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.406); called by muse, mutect2
- RYR3 | c.6694C>A p.L2232M | Missense Mutation (SNP) | VAF 38/303 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHPK | c.49G>C p.V17L | Missense Mutation (SNP) | VAF 27/396 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2
- SKI | c.145A>G p.K49E | Missense Mutation (SNP) | VAF 27/281 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- SLC27A6 | c.385G>T p.G129C | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC6A4 | c.1070G>A p.C357Y | Missense Mutation (SNP) | VAF 46/474 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SLU7 | c.566A>G p.D189G | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- SOX7 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 50/1231 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TAOK2 | c.1847A>G p.Q616R | Missense Mutation (SNP) | VAF 68/728 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); called by muse, mutect2
- THBS1 | c.871G>T p.V291L | Missense Mutation (SNP) | VAF 82/486 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TLR4 | c.1853T>G p.M618R (on ENST00000355622 / NM_138554.5; = p.M578R on NM_003266.4) | Missense Mutation (SNP) | VAF 31/814 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- TTC28 | c.5387C>G p.T1796S | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- UAP1L1 | c.913G>T p.V305L | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2
- USP9X | c.7615G>T p.A2539S | Missense Mutation (SNP) | VAF 24/377 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2
- ZIC3 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 56/253 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.368); called by muse, varscan2
- ABCB4 | c.1422G>A p.V474= | Silent (SNP) | VAF 146/655 reads (22%) | called by muse, mutect2, varscan2
- ADGB | c.3537T>C p.G1179= | Silent (SNP) | VAF 13/165 reads (8%) | called by muse, mutect2
- ADGRL3 | c.3189G>A p.V1063= (on ENST00000506720 / NM_001322402.2; = p.V995= on NM_015236.6) | Silent (SNP) | VAF 54/996 reads (5%) | catalogued as COSV101546800; called by muse, mutect2
- ASB10 | c.186G>A p.V62= | Silent (SNP) | VAF 26/404 reads (6%) | called by muse, mutect2
- CFH | c.1485G>T p.G495= | Silent (SNP) | VAF 190/914 reads (21%) | catalogued as COSV66409223; called by muse, mutect2, varscan2
- CYP2C8 | c.18C>G p.V6= | Silent (SNP) | VAF 16/372 reads (4%) | called by muse, mutect2
- CYP3A4 | c.249T>C p.A83= | Silent (SNP) | VAF 22/519 reads (4%) | called by muse, mutect2
- DNAH5 | c.7461G>T p.A2487= | Silent (SNP) | VAF 84/493 reads (17%) | catalogued as COSV54252339; called by muse, mutect2, varscan2
- ERGIC1 | c.120C>T p.F40= | Silent (SNP) | VAF 28/514 reads (5%) | called by muse, mutect2
- FAM20C | c.1185G>T p.L395= | Silent (SNP) | VAF 48/744 reads (6%) | called by muse, mutect2
- FAM90A10P | c.1077C>A p.V359= | Silent (SNP) | VAF 75/1346 reads (6%) | called by muse, mutect2
- ILDR2 | c.1500G>A p.A500= | Silent (SNP) | VAF 30/264 reads (11%) | called by muse, mutect2
- LSMEM2 | c.243G>T p.P81= | Silent (SNP) | VAF 49/423 reads (12%) | called by muse, mutect2, varscan2
- MMP9 | c.150C>T p.Y50= | Silent (SNP) | VAF 26/776 reads (3%) | catalogued as rs1203612981; called by muse, mutect2
- MSH3 | c.870G>T p.L290= | Silent (SNP) | VAF 97/807 reads (12%) | called by muse, mutect2, varscan2
- MSH4 | c.2574C>G p.V858= | Silent (SNP) | VAF 10/254 reads (4%) | called by muse, mutect2
- NCOR2 | c.4230C>T p.A1410= | Silent (SNP) | VAF 15/323 reads (5%) | called by muse, mutect2
- OR10Q1 | c.663C>G p.V221= | Silent (SNP) | VAF 62/549 reads (11%) | called by muse, mutect2, varscan2
- OR13F1 | c.789C>T p.S263= | Silent (SNP) | VAF 36/570 reads (6%) | catalogued as rs761577289, COSV58250861; called by muse, mutect2
- OR1C1 | c.687C>A p.T229= | Silent (SNP) | VAF 30/308 reads (10%) | called by muse, mutect2
- OR5L2 | c.129G>T p.L43= | Silent (SNP) | VAF 131/697 reads (19%) | called by muse, mutect2, varscan2
- OXER1 | c.408C>T p.A136= | Silent (SNP) | VAF 19/247 reads (8%) | called by muse, mutect2
- PCDH8 | c.2082C>T p.D694= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as rs900643825, COSV58811215; called by muse, mutect2
- PCDHGA5 | c.781C>T p.L261= | Silent (SNP) | VAF 34/332 reads (10%) | called by muse, mutect2
- PLD3 | c.936C>T p.L312= | Silent (SNP) | VAF 59/774 reads (8%) | catalogued as rs770404176; called by muse, mutect2
- PPP1R37 | c.765G>A p.A255= | Silent (SNP) | VAF 40/442 reads (9%) | catalogued as rs940068116; called by muse, mutect2
- PRIMPOL | c.1554T>C p.D518= | Silent (SNP) | VAF 19/580 reads (3%) | called by muse, mutect2
- RASSF8 | c.552G>T p.L184= | Silent (SNP) | VAF 46/570 reads (8%) | called by muse, mutect2
- RECQL5 | c.588C>T p.T196= | Silent (SNP) | VAF 15/402 reads (4%) | catalogued as rs1326574056; called by muse, mutect2
- SPTA1 | c.429G>A p.L143= | Silent (SNP) | VAF 50/1572 reads (3%) | called by muse, mutect2
- TASOR2 | c.6099T>A p.P2033= | Silent (SNP) | VAF 73/501 reads (15%) | called by muse, mutect2, varscan2
- VCAN | c.1467G>A p.Q489= | Silent (SNP) | VAF 66/1440 reads (5%) | catalogued as COSV99428001; called by muse, mutect2
- ZNF423 | c.579C>A p.I193= (on ENST00000563137 / NM_001379286.1; = p.I185= on NM_015069.4) | Silent (SNP) | VAF 27/710 reads (4%) | called by muse, mutect2
- ZNF460 | c.102G>A p.Q34= | Silent (SNP) | VAF 59/331 reads (18%) | catalogued as COSV64415707; called by muse, mutect2, varscan2
- AURKB | c.48+71T>A | Intron (SNP) | VAF 40/239 reads (17%) | called by muse, mutect2, varscan2
- CD40 | c.-24C>T | 5'UTR (SNP) | VAF 122/716 reads (17%) | catalogued as rs1350354855; called by muse, varscan2
- CDCA7L | c.*32A>G | 3'UTR (SNP) | VAF 21/552 reads (4%) | called by muse, mutect2
- COL18A1 | c.3972+39C>T | Intron (SNP) | VAF 274/619 reads (44%) | called by muse, mutect2, varscan2
- DDB2 | c.1024-11C>T | Intron (SNP) | VAF 31/1243 reads (2%) | called by muse, mutect2
- FMO9P | n.235T>C | RNA (SNP) | VAF 30/622 reads (5%) | called by muse, mutect2
- HHLA1 | c.1469+978C>A | Intron (SNP) | VAF 23/672 reads (3%) | called by muse, mutect2
- HS6ST2 | c.948-40070C>G | Intron (SNP) | VAF 131/364 reads (36%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.1944C>A | RNA (SNP) | VAF 28/918 reads (3%) | called by muse, mutect2
- JMJD8 | c.*853G>A | 3'UTR (SNP) | VAF 107/345 reads (31%) | catalogued as rs957514736; called by muse, mutect2, varscan2
- MIR1246 | n.54T>A | RNA (SNP) | VAF 18/222 reads (8%) | called by muse, mutect2
- MIR182 | n.20G>A | RNA (SNP) | VAF 30/136 reads (22%) | catalogued as rs561268259; called by muse, mutect2, varscan2
- MTNR1B | chr11:92984869 C>T | 3'Flank (SNP) | VAF 35/371 reads (9%) | called by muse, mutect2
- NCBP2 | c.78+440C>T | Intron (SNP) | VAF 74/467 reads (16%) | catalogued as rs1216907784; called by muse, mutect2, varscan2
- NQO2-AS1 | n.593-4039T>A | Intron (SNP) | VAF 22/264 reads (8%) | called by muse, mutect2
- PIK3CD | c.-138+2051C>A | Intron (SNP) | VAF 152/644 reads (24%) | catalogued as COSV66098851; called by muse, mutect2, varscan2
- SEC31A | c.2503-763A>G | Intron (SNP) | VAF 17/271 reads (6%) | called by muse, mutect2
- XIRP2 | c.-76G>A | 5'UTR (SNP) | VAF 57/490 reads (12%) | catalogued as COSV54729195; called by muse, mutect2, varscan2
